Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA6X, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA6X-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age)

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Bladder mass, high grade Ta on outside pathology

Specimens Submitted:

1: Left lateral bladder wall

DIAGNOSIS:

1. Left lateral bladder wall:

Tumor Type:

Invasive urothelial carcinoma with glandular differentiation

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

Papillary and flat

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

ICD O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder, lateral wall
C67.2
4/30/14

COMMENT: By immunostains, the tumor was positive for p63 (4A4) and CK7 and negative for PSA, PSMA and ERG.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received in _____, labeled "left lateral bladder wall", and consists of multiple pieces of tan soft tissue ranging from 0.2 to 1.2 cm. The specimen is entirely submitted one cassette. TPS taken. Summary of sections:

Summary of Sections:

Part 1: Left lateral bladder wall

Blocks Block Designation PCs

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

1 {not entered} 6

Special Studies:

Result	Special Stain	Comment
	NEGATIVE.	
	VIMEN	
	PSA	
	PSMA	
	4A4/P63	
	ERG.	
	CK7	
	IMM RECUT	

Source: NCI Genomic Data Commons file 982541c7-9e68-4b2c-b4eb-cb26e0de3134 (TCGA-DK-AA6X.669554D5-C608-4028-B24E-1F2129FA0925.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).